Somatic mutation profile of tumor specimen TCGA-B2-A4SR-01A (aliquot TCGA-B2-A4SR-01A-11D-A25V-10) from TCGA case TCGA-B2-A4SR, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 62.0 years (22,637 days).
Specimen TCGA-B2-A4SR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 931514a3-458d-4c2f-a5a2-30ab90167fdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-A4SR-10A (Blood Derived Normal), aliquot TCGA-B2-A4SR-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8bf2ebd-e0fd-4a03-95ff-0938f92293a9

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 12, Frame Shift Del 4, In Frame Del 2, Splice Region 2, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOB | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs761908783, COSV100878795; called by muse, mutect2, varscan2
- BAZ1A | c.327T>A p.F109L | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100701076; called by muse, mutect2
- BVES | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV100114565; called by muse, mutect2, varscan2
- CD3D | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 20/194 reads (10%) | catalogued as rs201994476, COSV100329309; called by muse, mutect2, varscan2
- COL6A6 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs758304492, COSV62017228; called by muse, mutect2, varscan2
- FAM172A | c.923C>G p.A308G | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as COSV101232630; called by muse, mutect2, varscan2
- FBF1 | c.2775G>A p.Q925= (on ENST00000586717; = p.Q940= on NM_001319193.1) | Splice Region (SNP) | VAF 14/47 reads (30%) | catalogued as rs147541272, COSV100044612; called by muse, mutect2, varscan2
- FREM2 | c.7814T>G p.I2605R | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV99746034; called by muse, mutect2, varscan2
- GNPTAB | c.2942C>T p.S981L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100171505; called by muse, mutect2, varscan2
- IHO1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as rs1244734182, COSV99605665; called by muse, mutect2, varscan2
- LAMA2 | c.2062A>G p.I688V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV101369821; called by muse, mutect2, varscan2
- LAMC2 | c.1951G>T p.G651C | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99916861; called by muse, mutect2, varscan2
- LRP1 | c.12056A>T p.D4019V | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV99673802; called by muse, mutect2, varscan2
- MAST4 | c.2657A>G p.E886G (on ENST00000403625 / NM_001164664.2; = p.E697G on NM_015183.3) | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842301; called by muse, mutect2, varscan2
- MGAT5B | c.1970C>A p.P657Q (on ENST00000569840 / NM_001199172.2; = p.P655Q on NM_144677.3) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.224); catalogued as rs769346236, COSV100046998, COSV100048330; called by muse, mutect2, varscan2
- MS4A12 | c.414T>C p.S138= | Splice Region (SNP) | VAF 10/202 reads (5%) | catalogued as COSV99188415; called by muse, mutect2
- OR11H1 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 96/748 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV53271744, COSV99421490; called by muse, varscan2
- OSBPL3 | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100513518; called by muse, mutect2, varscan2
- PKHD1L1 | c.6025G>T p.G2009W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101005047; called by muse, mutect2, varscan2
- PLIN3 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.692); catalogued as rs202240827, COSV55734960; called by muse, mutect2
- RASGRP3 | c.652A>G p.R218G | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101274647; called by muse, mutect2, varscan2
- RPL7A | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV100034491; called by muse, mutect2, varscan2
- TDRD9 | c.2602A>T p.T868S | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100174475; called by muse, mutect2, varscan2
- TGOLN2 | c.1238T>A p.V413D | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99964908; called by muse, mutect2, varscan2
- ALDH1B1 | c.1117_1131del p.Y373_G377del | In Frame Del (DEL) | VAF 48/233 reads (21%) | called by mutect2, pindel, varscan2
- DNAH3 | c.9425del p.L3142Cfs*14 | Frame Shift Del (DEL) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- GPR182 | c.928dup p.M310Nfs*32 | Frame Shift Ins (INS) | VAF 30/133 reads (23%) | called by mutect2, pindel, varscan2
- MAU2 | c.922_924del p.K308del | In Frame Del (DEL) | VAF 26/107 reads (24%) | called by mutect2, pindel, varscan2
- PARP14 | c.792del p.P265Lfs*7 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- SARS2 | c.186del p.F63Sfs*34 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- XRN1 | c.446del p.Y149Ffs*3 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | called by mutect2, pindel, varscan2
- BIRC6 | c.3117A>G p.S1039= | Silent (SNP) | VAF 45/182 reads (25%) | catalogued as COSV101427726; called by muse, mutect2, varscan2
- BPIFB4 | c.705T>A p.P235= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV100971378; called by muse, mutect2
- FAM237A | c.462G>A p.L154= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV101484346; called by muse, mutect2
- KRT1 | c.1920C>T p.S640= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as rs1436500384, COSV52868110; called by muse, mutect2
- MCEMP1 | c.45A>G p.Q15= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV100365260; called by muse, mutect2, varscan2
- NUTM2F | c.1362C>T p.V454= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as COSV99479779; called by muse, mutect2, varscan2
- OR11H4 | c.54C>A p.I18= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as COSV100197324, COSV59559880; called by muse, mutect2, varscan2
- PRMT6 | c.510C>G p.V170= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV100791114; called by muse, mutect2, varscan2
- TAF6 | c.915T>A p.I305= | Silent (SNP) | VAF 10/227 reads (4%) | catalogued as COSV100612570; called by muse, mutect2
- TMEM132E | c.1266C>A p.S422= (on ENST00000321639; = p.S512= on NM_001304438.2) | Silent (SNP) | VAF 78/282 reads (28%) | catalogued as COSV100395856; called by muse, varscan2
- WDR41 | c.369C>T p.T123= | Silent (SNP) | VAF 47/200 reads (24%) | catalogued as rs1200366332, COSV99688995; called by muse, varscan2
- ZNF532 | c.2076T>G p.V692= | Silent (SNP) | VAF 18/462 reads (4%) | catalogued as COSV100265816, COSV100265874; called by muse, mutect2
- PKD1L2 | n.2972C>G | RNA (SNP) | VAF 76/281 reads (27%) | called by muse, mutect2, varscan2
